Surgical pathology report (de-identified scan), TCGA case TCGA-G9-6378, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Roswell Park, specimen TCGA-G9-6378-01A (Primary Tumor).

[page 1 of 2]
SPECIMENS:

A. PROSTATE

SPECIMEN(S):

A. PROSTATE

TCGA - G9 - 6378

GROSS DESCRIPTION:

A. PROSTATE

Received fresh labeled with the patient's identification and "prostate" is a 44-g resected prostate gland measuring 4 cm from left lateral to right lateral, 4 cm from anterior to posterior, 3 cm from apex to base. Capsule is red, smooth, and intact. Ink code: Anterior-orange, apex-red, base-blue, right lateral-green, left lateral-yellow, posterior-black. After removal of at apex and base, the prostate weighs 25 g and has a nodular pink-tan parenchyma. The right seminal vesicle is 4.2 x 1.9 x 0.4cm, the left is 5.8 x 2 x 0.6 cm; they consist of cystic tan tissue. The right vas deferens is 1 x 0.4 cm and the left is 1.7 x 0.4 cm; they consist of a tubular tan tissue. Tissue is procured (13 g). Submitted entirely:

A1: right apex, perpendicular sections

A2: left apex, perpendicular sections

A3: level 1, right anterior

A4: level 1, right posterior

A5: level 1, left anterior

A6: level 1, left posterior

A7: level 2, anterior and right lateral capsule

A8: level 2, posterior and left lateral capsule

A9: level 3, right anterior

A10: level 3, right posterior

A11: level 3, left anterior

A12: level 3, left posterior

A13: level 4, anterior and right lateral capsule

A14: level 4, posterior and left lateral capsule

A15-A16: right mid base, perpendicular sections

A17-A19: left mid base, perpendicular sections

A20-A21: right lateral base, perpendicular sections

A22-A23: left lateral base, perpendicular sections

A24: base with right seminal vesicle and vas deferens

A25: base with left seminal vesicle and vas deferens

A26: right seminal vesicle and vas deferens

A27: left seminal vesicle and vas deferens

DIAGNOSIS:

A. PROSTATE, RADICAL PROSTATECTOMY:

- ADENOCARCINOMA, GLEASON SCORE 3+4 (7/10) INVOLVING
APPROXIMATELY 10% OF THE EXAMINED TISSUE AND FOCALLY
EXTENDING TO RESECTION MARGIN

SYNOPTIC REPORT - PROSTATE GLAND

Specimens Involved

Specimens: A: PROSTATE

Location: Left

Right

Posterior lateral

Apical

Basal

Anterior

WHO CLASSIFICATION

Epithelial tumors

Adenocarcinoma 8140/3

Multicentricity: Yes

Gland Involvement: 10%

Gleason Grade/Sum:: Grade 3 + 4 , Sum 7

High Grade PIN Present: Yes

[page 2 of 2]
[REDACTED]

Perineural Invasion: Yes
Vascular/Lymphatic Invasion: No
Seminal Vesicle Invasion: No
Periprostatic Fat Involved: No
Bladder Neck Involved: No
Margins Involvement: Yes
Location: Left mid base
Linear Distance: Focal (1-10mm)
Frozen Performed: No
Lymph Nodes: No lymph nodes sampled
Other Pathologic Findings: None identified
Pathological Staging (pTNM): T 2x N x M x
Pathological staging is based on the AJCC Cancer Staging Manual, 7th Edition
pT2c: Tumor involves both lobes
pMX: Cannot be assessed
Comment(s): Tumor extends to resection margin in a single focus- 1.1 mm linear distance.

CLINICAL HISTORY:

None given

PRE-OPERATIVE DIAGNOSIS:

Prostate cancer

[REDACTED]

Source: NCI Genomic Data Commons file 62065e04-1831-46bb-92bb-84ae8c26230c (TCGA-G9-6378.425008C5-919C-45B3-BEB7-2392D6866FFB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).